CGCI case BLGSP-71-06-00098 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/853704eb-f49e-4509-82dc-47a85c7335f2

Demographics
Sex at birth: female; Race: black or african american; Age at index: 8 years; Vital status: Dead; Days to death: 11 days.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 8.6 years (3,134 days); Year of diagnosis: 2014; Method of diagnosis: Incisional Biopsy; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 11 days; Burkitt lymphoma clinical variant: Endemic.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 50; ECOG performance status: 3.
- Days to follow up: 5 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 11.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.

Other clinical attributes
- Day 0: Weight: 22 kg; Height: 24 cm; BMI: 381.9.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-06-00098-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Cervical; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Incisional Biopsy; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00098-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 10.
  Slide BLGSP-71-06-00098-01A-01-S1-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 10.
- Sample BLGSP-71-06-00098-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00098-01-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-06-00098-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-06-00098-01-BCL2: Tissue microarray coordinates: B2,D4,A5.
  Slide BLGSP-71-06-00098-01-CD3: Tissue microarray coordinates: B2,D4,A5.
  Slide BLGSP-71-06-00098-01-BCL6: Tissue microarray coordinates: B2,D4,A5.
  Slide BLGSP-71-06-00098-01-HE-1: Tissue microarray coordinates: B2,D4,A5.
  Slide BLGSP-71-06-00098-01-CD10: Tissue microarray coordinates: B2,D4,A5.
  Slide BLGSP-71-06-00098-01-Ki67: Tissue microarray coordinates: B2,D4,A5.
  Slide BLGSP-71-06-00098-01-CD20: Tissue microarray coordinates: B2,D4,A5.
- Sample BLGSP-71-06-00098-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen; Days to sample procurement: 5 days; Method of sample procurement: Other; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Days from index date to last known alive: 5; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed: Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
